Somatic mutation profile of tumor specimen TCGA-TN-A7HL-01A (aliquot TCGA-TN-A7HL-01A-11D-A34J-08) from TCGA case TCGA-TN-A7HL, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.5 years (21,731 days).
Specimen TCGA-TN-A7HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b1ffacc-b758-44d2-ab34-f155085ae061.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TN-A7HL-10A (Blood Derived Normal), aliquot TCGA-TN-A7HL-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/756aa867-40b1-4458-8ede-ad332ec7c3f6

The open-access MAF lists 678 somatic variants for this specimen: 487 protein-altering or splice-affecting, 183 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 422, Silent 183, Nonsense Mutation 50, Splice Site 8, Splice Region 5, Intron 4, RNA 2, 3'UTR 1, 3'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1436G>C p.R479T (on ENST00000399959; = p.R480T on NM_001356.5) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as rs1569240005, COSV101302315, COSV67863554; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1435C>T p.R479* (on ENST00000281708 / NM_001349798.2; = p.R399* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | hotspot (GDC flag); catalogued as COSV55894141, COSV55894999, COSV55908957; called by muse, mutect2
- FGFR3 | c.*194G>A | 3'UTR (SNP) | VAF 46/217 reads (21%) | catalogued as rs28931614, CM940785, CM940786, CX090489, COSV53399372, COSV99602429; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/103 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADAT | c.1175C>G p.S392* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100528538; called by muse, mutect2, varscan2
- ABAT | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99190863; called by muse, mutect2, varscan2
- ABCA4 | c.3385C>A p.R1129S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs779426136, CM970010, COSV100932998; called by muse, mutect2, varscan2
- ABRAXAS1 | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.047); catalogued as COSV99788355; called by muse, mutect2, varscan2
- ACLY | c.1439C>G p.P480R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100709478; called by muse, mutect2, varscan2
- ACSBG1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.142); catalogued as rs1303683057, COSV99356913; called by muse, mutect2
- ACSBG2 | c.1394G>C p.C465S | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99397105; called by muse, mutect2, varscan2
- ADAM21 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs144766277; called by muse, mutect2, varscan2
- ADCY10 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.551); catalogued as COSV63239695; called by muse, mutect2, varscan2
- ADCY8 | c.2788C>T p.R930* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | catalogued as rs765725170, COSV53897461, COSV53900478; called by muse, mutect2, varscan2
- ADGRG4 | c.3755C>G p.S1252C | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54960357; called by muse, mutect2, varscan2
- AFAP1 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.93); catalogued as COSV100631029; called by muse, mutect2, varscan2
- AHNAK2 | c.3871C>G p.L1291V | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV100315036; called by muse, mutect2, varscan2
- ALB | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV99890466; called by muse, mutect2, varscan2
- ALMS1 | c.9014C>T p.S3005L | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.682); catalogued as COSV100040817; called by muse, mutect2, varscan2
- ALPK1 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV99452821; called by muse, mutect2, varscan2
- ANGPT4 | c.468C>T p.L156= | Splice Region (SNP) | VAF 14/75 reads (19%) | catalogued as COSV101124604; called by muse, mutect2, varscan2
- ANKFN1 | c.1152G>C p.Q384H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100592958; called by muse, mutect2
- ANKLE2 | c.1873G>C p.D625H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.466); catalogued as COSV100513874; called by muse, mutect2, varscan2
- ANKRD17 | c.1880C>G p.S627C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428362; called by muse, mutect2, varscan2
- ANKRD26 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101062840, COSV65776214; called by muse, mutect2, varscan2
- AP1AR | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as rs552933023, COSV99914058; called by muse, mutect2, varscan2
- APCS | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV54817619, COSV99661119; called by muse, mutect2, varscan2
- APH1A | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52528642; called by muse, mutect2
- ARHGAP29 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99557412; called by muse, mutect2, varscan2
- ARHGAP35 | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as COSV101350615; called by muse, mutect2, varscan2
- ARHGEF7 | c.691G>A p.G231S (on ENST00000375741 / NM_001113511.2; = p.G53S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174207091, COSV99520720; called by muse, mutect2, varscan2
- ARSL | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV101140351; called by muse, mutect2, varscan2
- ATAD5 | c.4787C>T p.S1596L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100429548; called by muse, mutect2, varscan2
- ATL1 | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV100612857; called by muse, mutect2, varscan2
- ATP13A5 | c.84C>G p.D28E | Missense Mutation (SNP) | VAF 9/258 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV100664601; called by muse, mutect2
- ATP2B1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99665050; called by muse, mutect2, varscan2
- ATP2B1 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV53812817, COSV99665052; called by muse, mutect2, varscan2
- ATP2B2 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as COSV100659454, COSV59505706; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2522C>G p.S841* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100376763; called by muse, mutect2, varscan2
- ATP8A1 | c.2763G>T p.L921F | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as COSV100044584; called by muse, mutect2, varscan2
- ATRN | c.2219C>G p.S740C | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99496397; called by muse, mutect2, varscan2
- BAZ1B | c.3629A>T p.H1210L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100289469; called by muse, mutect2, varscan2
- BECN1 | c.618G>C p.K206N | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100830984; called by muse, mutect2, varscan2
- BMP15 | c.796A>C p.T266P | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99399132; called by muse, mutect2, varscan2
- BRINP1 | c.2098C>G p.R700G | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56291761, COSV99774028; called by muse, mutect2, varscan2
- BUB1B | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.152); catalogued as COSV99806425; called by muse, mutect2, varscan2
- C19orf44 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.148); catalogued as rs1490438618, COSV99684847; called by muse, mutect2
- C1orf112 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as COSV99609240; called by muse, mutect2, varscan2
- C2CD5 | c.1356G>C p.Q452H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100448360; called by muse, mutect2, varscan2
- C6 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99666223; called by muse, mutect2, varscan2
- C7 | c.2303C>T p.S768L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1429664375, COSV100495233; called by muse, mutect2, varscan2
- CACNA1I | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100358910; called by muse, mutect2, varscan2
- CASK | c.2638G>C p.D880H (on ENST00000378163 / NM_001367721.1; = p.D875H on NM_003688.3) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV59372251, COSV59374561; called by muse, mutect2, varscan2
- CBX8 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV53936837, COSV99485697; called by muse, mutect2, varscan2
- CCDC146 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV99591991; called by muse, mutect2
- CCDC27 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99621906; called by muse, mutect2, varscan2
- CCDC8 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.772); catalogued as COSV56774970; called by muse, mutect2, varscan2
- CCNK | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101110274; called by muse, mutect2, varscan2
- CCPG1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV100196842; called by muse, mutect2, varscan2
- CCRL2 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as rs754286699, COSV100644947; called by muse, mutect2, varscan2
- CCT6A | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99303170; called by muse, mutect2, varscan2
- CD163L1 | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV58016126, COSV58022652; called by muse, mutect2, varscan2
- CDC27 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99293392; called by muse, mutect2, varscan2
- CDCP2 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100313242, COSV61286674; called by muse, varscan2
- CDK15 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.35); catalogued as COSV99642535; called by muse, mutect2, varscan2
- CELF1 | c.1195G>A p.E399K (on ENST00000358597 / NM_001376422.1; = p.E395K on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100136584; called by muse, mutect2, varscan2
- CELSR1 | c.2001G>A p.M667I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs1413770797, COSV99416361, COSV99420035; called by muse, mutect2
- CELSR2 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99602816; called by muse, mutect2, varscan2
- CERS3 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.257); catalogued as COSV99430904; called by muse, mutect2, varscan2
- CERT1 | c.877G>C p.E293Q (on ENST00000405807 / NM_001130105.1; = p.E165Q on NM_005713.3) | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV99782691; called by muse, mutect2, varscan2
- CFAP43 | c.2850G>C p.L950F | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV99530271; called by muse, mutect2, varscan2
- CFAP43 | c.2749G>C p.E917Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99530272; called by muse, mutect2, varscan2
- CFHR1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100258548, COSV57628478; called by muse, mutect2, varscan2
- CHD5 | c.603C>G p.F201L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV52411968; called by muse, mutect2, varscan2
- CHRND | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV99285447; called by muse, mutect2, varscan2
- CKB | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as COSV100818892; called by muse, mutect2
- CKS1B | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58315739; called by muse, mutect2, varscan2
- CLCNKB | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990175; called by muse, mutect2, varscan2
- CLDN8 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99729612; called by muse, mutect2, varscan2
- CLIC1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs151146724; called by muse, mutect2
- CMYA5 | c.3207C>A p.F1069L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.087); catalogued as COSV101483716, COSV71406190; called by muse, mutect2, varscan2
- CNDP1 | c.1335C>G p.I445M | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100722140; called by muse, mutect2, varscan2
- CNOT6L | c.745C>G p.L249V (on ENST00000504123 / NM_001286790.2; = p.L244V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1365262150, COSV99361174; called by muse, mutect2
- CNTRL | c.6844G>A p.D2282N | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); catalogued as COSV99440761; called by muse, mutect2, varscan2
- COBL | c.686-1G>A p.X229_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99470895; called by muse, mutect2, varscan2
- COL22A1 | c.2614G>T p.E872* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100275597, COSV100277434; called by muse, mutect2, varscan2
- COL4A4 | c.4163G>C p.R1388T | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV100305942; called by muse, mutect2, varscan2
- COL6A3 | c.2428C>A p.Q810K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99795826; called by muse, mutect2, varscan2
- COQ9 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99345624; called by muse, mutect2, varscan2
- CORO2A | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100673968; called by muse, mutect2, varscan2
- COX4I2 | c.159C>G p.F53L | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV101064165; called by muse, mutect2, varscan2
- CPA3 | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99935885; called by muse, mutect2, varscan2
- CREBBP | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99268180; called by muse, mutect2, varscan2
- CREBBP | c.4249T>C p.Y1417H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52135767, COSV99268182; called by muse, mutect2, varscan2
- CRHBP | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV99169434; called by muse, mutect2, varscan2
- CSMD2 | c.5598C>G p.F1866L | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV99584485; called by muse, mutect2, varscan2
- CTAGE1 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV101194390; called by muse, mutect2, varscan2
- CTAGE1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.805); catalogued as COSV101194391; called by muse, mutect2, varscan2
- CTNND2 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 24/143 reads (17%) | catalogued as COSV100470201; called by muse, mutect2, varscan2
- CYP4B1 | c.1272C>G p.V424= | Splice Region (SNP) | VAF 20/114 reads (18%) | catalogued as COSV99596652; called by muse, mutect2, varscan2
- DAPL1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs745794395, COSV59353180; called by muse, mutect2, varscan2
- DCBLD2 | c.542T>C p.L181S | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100471205; called by muse, mutect2, varscan2
- DCLRE1C | c.1870C>G p.L624V (on ENST00000378278 / NM_001350965.2; = p.L509V on NM_022487.4) | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as COSV100542939; called by muse, mutect2, varscan2
- DCST1 | c.1359G>A p.M453I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV99792576; called by muse, varscan2
- DCST1 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99664613; called by muse, mutect2, varscan2
- DCX | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100576135; called by muse, mutect2, varscan2
- DDOST | c.448G>A p.D150N (on ENST00000415136; = p.D133N on NM_005216.5) | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100387083; called by muse, mutect2, varscan2
- DDX3X | c.1558G>C p.D520H (on ENST00000399959; = p.D521H on NM_001356.5) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101302317; called by muse, mutect2, varscan2
- DDX59 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs753497178, COSV100494310; called by muse, mutect2, varscan2
- DENND2B | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100567024; called by muse, mutect2, varscan2
- DEPDC5 | c.2546C>G p.S849C (on ENST00000400246; = p.S918C on NM_014662.5) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99834051; called by muse, mutect2, varscan2
- DHX15 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs754378482, COSV61027175; called by muse, mutect2, varscan2
- DIDO1 | c.3655C>T p.Q1219* | Nonsense Mutation (SNP) | VAF 39/183 reads (21%) | catalogued as COSV99824345; called by muse, mutect2, varscan2
- DLG1 | c.2665G>A p.E889K (on ENST00000419354 / NM_001290983.1; = p.E911K on NM_004087.2) | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV100014438; called by muse, mutect2, varscan2
- DNAAF4 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV100336511; called by muse, mutect2, varscan2
- DNAH11 | c.7285G>C p.D2429H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100176192; called by muse, mutect2
- DNM3 | c.1194C>T p.I398= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100797716; called by muse, mutect2
- DOCK2 | c.3342G>C p.M1114I | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99909571, COSV99914909; called by muse, mutect2, varscan2
- DRC1 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV56530311, COSV99984867; called by muse, mutect2, varscan2
- DRD3 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.236); catalogued as COSV99879059; called by muse, mutect2, varscan2
- DSP | c.5527C>G p.L1843V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV101131155; called by muse, mutect2, varscan2
- DST | c.22046C>T p.S7349L (on ENST00000361203 / NM_001374722.1; = p.S5059L on NM_015548.5) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99749589; called by muse, mutect2
- EFCAB13 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58948769; called by muse, mutect2, varscan2
- EFCC1 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs770823944, COSV71401748; called by muse, mutect2, varscan2
- EHBP1L1 | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1458855443, COSV100499558; called by muse, mutect2, varscan2
- EIF4G2 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100379316; called by muse, mutect2, varscan2
- ELP1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101010268; called by muse, mutect2, varscan2
- ELP2 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100626669; called by muse, mutect2, varscan2
- EOMES | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV99841599; called by muse, mutect2, varscan2
- ERCC6L2 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99998155; called by muse, mutect2, varscan2
- ERICH3 | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs779101589, COSV58605623; called by muse, mutect2, varscan2
- ERVW-1 | c.220C>A p.H74N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV71259474, COSV71259508; called by muse, mutect2, varscan2
- ESF1 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as rs753392512, COSV99176240; called by muse, mutect2, varscan2
- EXOC1 | c.1935G>C p.R645S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100637716, COSV62122000; called by muse, mutect2, varscan2
- EXOC3L2 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.331); catalogued as COSV99374420; called by muse, mutect2, varscan2
- EXOSC10 | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as COSV100442041; called by muse, mutect2, varscan2
- FAM151A | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.944); catalogued as COSV100156694; called by muse, mutect2, varscan2
- FAM161B | c.1590-1G>C p.X530_splice (on ENST00000651776; = p.X467_splice on NM_152445.3) | Splice Site (SNP) | VAF 47/145 reads (32%) | catalogued as rs1287709653, COSV99679479; called by muse, mutect2, varscan2
- FAM234B | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99545268; called by muse, mutect2, varscan2
- FASTKD3 | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV52942850, COSV52944214; called by muse, mutect2, varscan2
- FAT3 | c.6151G>C p.E2051Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99960101; called by muse, mutect2, varscan2
- FBH1 | c.2135G>A p.G712E (on ENST00000362091 / NM_178150.3; = p.G763E on NM_032807.4) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100758558; called by muse, mutect2, varscan2
- FEN1 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99952751; called by muse, mutect2, varscan2
- FER | c.1452G>C p.E484D | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99811236; called by muse, mutect2, varscan2
- FGFBP2 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs749826832, COSV99469274; called by muse, varscan2
- FGFBP2 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV99469279; called by muse, varscan2
- FGL2 | c.1290G>A p.M430I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.529); catalogued as rs768221638, COSV99591993; called by muse, mutect2, varscan2
- FMNL2 | c.1568C>A p.S523* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99978624; called by muse, mutect2, varscan2
- FNBP4 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99771338; called by muse, mutect2, varscan2
- FOXD4L1 | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99380081; called by muse, mutect2, varscan2
- FRAS1 | c.4951C>T p.R1651* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs753960106, COSV99347169, COSV99347494; called by muse, varscan2
- FSIP2 | c.17210C>T p.S5737L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100553536, COSV100555890; called by muse, mutect2, varscan2
- GALNT14 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100203927; called by muse, mutect2, varscan2
- GALNT16 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV100545641; called by muse, mutect2
- GARRE1 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as rs1568535684, COSV100208905; called by muse, mutect2, varscan2
- GBP5 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs751275007, COSV100599947; called by muse, mutect2, varscan2
- GGT1 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 36/149 reads (24%) | catalogued as COSV99958429; called by muse, mutect2, varscan2
- GGTLC1 | c.516G>C p.E172D | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99600321; called by muse, mutect2, varscan2
- GIGYF2 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101003753; called by muse, mutect2, varscan2
- GIPC1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52874325; called by muse, mutect2, varscan2
- GNA15 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV99504953; called by muse, varscan2
- GNB3 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV57529779; called by muse, mutect2, varscan2
- GPN1 | c.571-1G>C p.X191_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99269722; called by muse, mutect2, varscan2
- GPR108 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99901087; called by muse, mutect2, varscan2
- GPR148 | c.887C>G p.T296S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as COSV99998461; called by muse, mutect2, varscan2
- GPR149 | c.1570G>C p.D524H | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs774642099, COSV101078020; called by muse, mutect2, varscan2
- GPRC6A | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100113903; called by muse, mutect2, varscan2
- GPX1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101346258; called by muse, varscan2
- GRIP1 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV99667560; called by muse, mutect2, varscan2
- GRIPAP1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100904140; called by muse, varscan2
- GRIPAP1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1458203057, COSV100904141; called by muse, varscan2
- GRM8 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770566859, COSV58802417; called by muse, mutect2, varscan2
- GSX2 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482457, COSV58842378; called by muse, mutect2, varscan2
- H4-16 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100797595; called by muse, mutect2, varscan2
- H4C12 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV100694731, COSV100694760, COSV100694763; called by muse, mutect2, varscan2
- HDGF | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100625565; called by muse, mutect2
- HEATR6 | c.3153G>T p.Q1051H | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99482034; called by muse, mutect2, varscan2
- HNRNPH2 | c.1261G>T p.G421* | Nonsense Mutation (SNP) | VAF 107/224 reads (48%) | catalogued as COSV100346835, COSV100347228; called by muse, mutect2, varscan2
- HOXB6 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as rs1379620786, COSV53312541; called by muse, mutect2, varscan2
- HOXC6 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1418007936, COSV54537408, COSV99678893; called by muse, mutect2, varscan2
- HPF1 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 16/152 reads (11%) | catalogued as COSV101097538; called by muse, varscan2
- HPF1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.817); catalogued as COSV101097539; called by muse, varscan2
- HPS3 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99937068; called by muse, varscan2
- ICE1 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as rs746004062, COSV56820551; called by muse, mutect2, varscan2
- IDE | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV99793699; called by muse, mutect2, varscan2
- IFNL2 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100122029; called by muse, mutect2, varscan2
- IGF2R | c.3587C>T p.S1196L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100806682; called by muse, mutect2, varscan2
- IGSF22 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.19); catalogued as rs1245230850, COSV100078953; called by muse, mutect2
- IGSF9 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63639034, COSV63639533; called by muse, mutect2, varscan2
- IL21 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 40/144 reads (28%) | catalogued as COSV52646210, COSV99144415; called by muse, mutect2, varscan2
- ILDR1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99877778; called by muse, mutect2, varscan2
- INPP5B | c.2642C>T p.S881F (on ENST00000373023; = p.S801F on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1450598768, COSV100886317; called by muse, mutect2
- INPPL1 | c.942G>A p.V314= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99995695; called by muse, mutect2
- IRF2 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV101165738; called by muse, mutect2, varscan2
- IRS4 | c.1781C>G p.S594* | Nonsense Mutation (SNP) | VAF 73/168 reads (43%) | catalogued as COSV100929391; called by muse, mutect2, varscan2
- ITPR3 | c.6732G>C p.W2244C | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100966790; called by muse, mutect2, varscan2
- ITPRID2 | c.3526G>C p.E1176Q | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV57471015; called by muse, mutect2, varscan2
- KANK4 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV62986374; called by muse, mutect2, varscan2
- KASH5 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.075); catalogued as COSV101483374; called by muse, mutect2
- KCNH8 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV100108048; called by muse, mutect2, varscan2
- KIAA1217 | c.1670G>C p.R557T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.962); catalogued as COSV100285998; called by muse, mutect2
- KIF3B | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100996280; called by muse, mutect2
- KIRREL1 | c.1870G>C p.D624H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100779159; called by muse, mutect2, varscan2
- KLF3 | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99789548; called by muse, mutect2, varscan2
- KLHL22 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs139279490; called by muse, mutect2, varscan2
- KNL1 | c.1886C>G p.S629C (on ENST00000346991 / NM_170589.5; = p.S603C on NM_144508.5) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs1246847135, COSV100706968, COSV61151238, COSV61152397; called by muse, mutect2, varscan2
- KRT23 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs373501029, COSV52927782; called by muse, mutect2, varscan2
- KRT85 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.191); catalogued as rs370269453; called by muse, mutect2, varscan2
- LARS1 | c.3358G>A p.D1120N (on ENST00000394434 / NM_020117.11; = p.D1093N on NM_016460.3) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as COSV99198438; called by muse, mutect2, varscan2
- LARS1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745880730, COSV99198439; called by muse, mutect2, varscan2
- LGALS3 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99582276; called by muse, mutect2, varscan2
- LIMS2 | c.154G>T p.E52* (on ENST00000355119 / NM_001161403.3; = p.E76* on NM_017980.4) | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV99760355; called by muse, mutect2, varscan2
- LNPEP | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1466330669, COSV99183460; called by muse, mutect2, varscan2
- LNX2 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100310399, COSV60337666; called by muse, mutect2, varscan2
- LPCAT1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.033); catalogued as COSV52039008; called by muse, mutect2, varscan2
- LRFN4 | c.1344C>G p.I448M | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100540610; called by muse, mutect2, varscan2
- LRP1 | c.3982G>A p.D1328N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV99673860; called by muse, mutect2, varscan2
- LRP1 | c.9544G>A p.V3182I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs200382578, COSV54510023; called by muse, mutect2, varscan2
- LRRC23 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.888); catalogued as COSV99145104; called by muse, varscan2
- LRRC23 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99145106; called by muse, varscan2
- LRRC49 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53009121; called by muse, mutect2, varscan2
- LRRC7 | c.4673T>G p.L1558R (on ENST00000651989 / NM_001370785.2; = p.L1478R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223790; called by muse, mutect2, varscan2
- LRRC8C | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100967868; called by muse, mutect2, varscan2
- LRRIQ1 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV101279238; called by muse, mutect2, varscan2
- LRRIQ1 | c.2191G>C p.E731Q | Missense Mutation (SNP) | VAF 125/647 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV101279240; called by muse, mutect2, varscan2
- LRRIQ1 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147514803, COSV101279730; called by muse, mutect2, varscan2
- LZIC | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV101021241; called by muse, mutect2, varscan2
- MACF1 | c.8132C>T p.S2711L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99240465; called by muse, mutect2, varscan2
- MACROD2 | c.1144G>T p.E382* (on ENST00000642719; = p.E354* on NM_080676.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99425503; called by muse, mutect2, varscan2
- MAP10 | c.2555C>G p.S852C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101406412; called by muse, mutect2, varscan2
- MAP2K4 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.044); catalogued as COSV100796072; called by muse, mutect2, varscan2
- MAP3K7 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100997429; called by muse, mutect2, varscan2
- MAPK1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53187829; called by muse, mutect2, varscan2
- MBD3 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99336808; called by muse, mutect2
- MCL1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV100329384; called by muse, mutect2, varscan2
- MEGF8 | c.1620G>C p.L540F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99233986; called by muse, mutect2, varscan2
- MELTF | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746238789, COSV99585693; called by muse, mutect2, varscan2
- MEST | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs551376794, COSV99784043; called by muse, mutect2, varscan2
- METTL2B | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as rs567098989, COSV99299583; called by muse, mutect2, varscan2
- MICU3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV100535982; called by muse, mutect2, varscan2
- MIOX | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs1338916954, COSV53313717; called by muse, mutect2, varscan2
- MKI67 | c.7416C>G p.F2472L | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.072); catalogued as COSV100896022; called by muse, mutect2, varscan2
- MMP13 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV99506240; called by muse, mutect2, varscan2
- MMRN1 | c.2636C>A p.S879* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV53337958, COSV99306255; called by muse, mutect2, varscan2
- MPDZ | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1221690314, COSV100060278, COSV59937541; called by muse, mutect2
- MRGPRX1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs567589026, COSV57107622; called by muse, mutect2, varscan2
- MROH8 | c.1389G>C p.M463I | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs1389913825, COSV99456448, COSV99456560; called by muse, varscan2
- MROH8 | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 104/390 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs764417200, COSV99456449; called by muse, varscan2
- MS4A7 | c.34C>G p.H12D | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100279287; called by muse, mutect2, varscan2
- MSL1 | c.1633C>T p.Q545* (on ENST00000398532 / NM_001365919.1; = p.Q282* on NM_001012241.2) | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100277957; called by muse, mutect2, varscan2
- MTCH1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1246778699, COSV65319658; called by muse, mutect2, varscan2
- MTOR | c.2899C>T p.H967Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.921); catalogued as COSV100815609; called by muse, mutect2, varscan2
- MTUS1 | c.3596C>T p.S1199L (on ENST00000262102 / NM_001363061.1; = p.S365L on NM_020749.4) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99286046; called by muse, mutect2, varscan2
- MUC16 | c.15839C>T p.S5280L | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as COSV67464577; called by muse, mutect2, varscan2
- MUC16 | c.5698G>A p.E1900K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV101197416; called by muse, mutect2, varscan2
- MUC5B | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1458742988, COSV101499951; called by muse, mutect2, varscan2
- MVP | c.2454G>A p.Q818= | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100651446; called by muse, mutect2, varscan2
- MYBPC2 | c.2737A>T p.S913C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100731512; called by muse, mutect2, varscan2
- MYH7 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs397516259, COSV100805563; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs773740053, COSV62525007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5A | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100697186; called by muse, mutect2, varscan2
- NAA25 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.089); catalogued as COSV55706059, COSV99927186; called by muse, mutect2, varscan2
- NAT1 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100306411; called by muse, mutect2, varscan2
- NAV2 | c.5396C>T p.S1799F (on ENST00000396087 / NM_001244963.2; = p.S1743F on NM_145117.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100215877; called by muse, mutect2, varscan2
- NCAPD2 | c.3265C>G p.L1089V | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs1421019529, COSV100216740, COSV100217391; called by muse, mutect2, varscan2
- NCOA5 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV99275079; called by muse, mutect2
- NCOA6 | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as COSV100749874; called by muse, varscan2
- NEDD1 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99900658; called by muse, mutect2, varscan2
- NFE2L2 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101229273; called by muse, mutect2, varscan2
- NIBAN3 | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 28/138 reads (20%) | catalogued as COSV99394752; called by muse, varscan2
- NKIRAS1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.739); catalogued as COSV100135026; called by muse, mutect2, varscan2
- NLRC3 | c.2010G>C p.K670N | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1429175863, COSV100072308; called by muse, mutect2, varscan2
- NLRX1 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs556602737, COSV99423503; called by muse, mutect2, varscan2
- NMNAT1 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101020355; called by muse, mutect2, varscan2
- NMUR1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759147244, COSV59403664, COSV59404015; called by muse, mutect2, varscan2
- NOS1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs529671468, COSV57607848; called by muse, mutect2, varscan2
- NOTCH1 | c.5590C>T p.Q1864* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99484195; called by muse, mutect2, varscan2
- NPHP3 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV100446538; called by muse, mutect2, varscan2
- NPHS2 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs768932711, COSV62636689; called by muse, mutect2, varscan2
- NSD1 | c.4901G>A p.R1634Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100728280; called by muse, mutect2, varscan2
- NSFL1C | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99401082; called by muse, mutect2, varscan2
- NUMA1 | c.3961C>T p.R1321C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.917); catalogued as rs754313223, COSV100705686; called by muse, mutect2, varscan2
- NUP153 | c.3547C>T p.Q1183* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100019605; called by muse, mutect2, varscan2
- NUP153 | c.3184C>G p.P1062A | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100019606; called by muse, mutect2, varscan2
- NUP54 | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 28/122 reads (23%) | catalogued as COSV99345072; called by muse, mutect2, varscan2
- NUP93 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV100359831, COSV100360032; called by muse, mutect2, varscan2
- NUTM2G | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as rs533234971, COSV100672501; called by muse, mutect2, varscan2
- OPRL1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs773088193, COSV100401862; called by muse, mutect2, varscan2
- OR1F1 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV100484334; called by muse, mutect2, varscan2
- OR4K1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99035406; called by muse, mutect2
- OR4K1 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV99578536; called by muse, mutect2
- OR5D16 | c.290C>G p.S97* | Nonsense Mutation (SNP) | VAF 62/277 reads (22%) | catalogued as COSV101003796; called by muse, mutect2, varscan2
- OXSR1 | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100309071, COSV61259409; called by muse, mutect2
- PABPC5 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100442040; called by muse, mutect2, varscan2
- PCDH10 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs1400031919, COSV52090235; called by muse, mutect2, varscan2
- PCDH17 | c.2479C>T p.Q827* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100931373; called by muse, mutect2, varscan2
- PCDHB3 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs1554272596, COSV50580977; called by muse, mutect2, varscan2
- PCDHGA12 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99337170; called by muse, mutect2, varscan2
- PCSK2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs540431424, COSV99358418; called by muse, mutect2, varscan2
- PDCD10 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV101208489; called by muse, mutect2, varscan2
- PDE6A | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99677621; called by muse, mutect2, varscan2
- PDE9A | c.443-1G>C p.X148_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99370865; called by muse, mutect2, varscan2
- PDZRN4 | c.2977A>G p.K993E (on ENST00000402685 / NM_001164595.2; = p.K735E on NM_013377.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1381256731, COSV100113308; called by muse, mutect2, varscan2
- PEG3 | c.4420G>A p.E1474K | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99686698; called by muse, mutect2, varscan2
- PGAP1 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1169639805, COSV100697940; called by muse, mutect2, varscan2
- PGAP4 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.45); catalogued as COSV100877748; called by muse, mutect2, varscan2
- PHF21A | c.1606-1G>C p.X536_splice (on ENST00000418153 / NM_001101802.3; = p.X490_splice on NM_016621.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 18/84 reads (21%) | catalogued as COSV99137996; called by muse, mutect2, varscan2
- PITPNM3 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1323377364, COSV99337772; called by muse, mutect2, varscan2
- PJVK | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99247344; called by muse, mutect2, varscan2
- PKHD1 | c.6223G>A p.E2075K | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.386); catalogued as COSV100580725; called by muse, mutect2, varscan2
- PLAA | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV101263475; called by muse, mutect2, varscan2
- PLK3 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV100220969; called by muse, mutect2
- PLSCR4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV61608946; called by muse, mutect2, varscan2
- POGZ | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.68); catalogued as COSV99652167; called by muse, mutect2, varscan2
- POLQ | c.5414C>T p.S1805L | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV99951371; called by muse, mutect2, varscan2
- POM121L12 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101374813; called by muse, mutect2, varscan2
- POTEE | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 93/365 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV100386535; called by muse, mutect2, varscan2
- POU2F3 | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99500590; called by muse, mutect2, varscan2
- PPIP5K2 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100383342; called by muse, mutect2, varscan2
- PPM1H | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955005; called by mutect2, varscan2
- PPP1R12B | c.2436C>G p.F812L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV51783953, COSV99294474; called by muse, mutect2, varscan2
- PPP5C | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99180816; called by muse, mutect2
- PPRC1 | c.4939G>C p.D1647H | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV99531227; called by muse, mutect2, varscan2
- PRAM1 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.731); catalogued as COSV99725114; called by muse, mutect2
- PRKAA1 | c.1649G>C p.C550S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100831330; called by muse, mutect2, varscan2
- PRKCQ | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV99576104; called by muse, mutect2, varscan2
- PRPF3 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV100254403; called by muse, mutect2
- PRPF39 | c.2002C>G p.P668A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.081); catalogued as COSV99360711; called by muse, mutect2, varscan2
- PRR27 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.157); catalogued as COSV100748749; called by muse, mutect2, varscan2
- PSMD4 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs769270518, COSV100924640; called by muse, mutect2, varscan2
- PTCH1 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs555332902, COSV59496700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.209C>T p.S70F (on ENST00000421990 / NM_001136042.2; = p.S52F on NM_025267.3) | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as rs1255835544, COSV100799172; called by muse, mutect2, varscan2
- PTPRE | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs368612656; called by muse, mutect2, varscan2
- PTPRG | c.2904G>T p.E968D | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as COSV99872305; called by muse, mutect2, varscan2
- PTPRJ | c.1683G>C p.K561N | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.395); catalogued as COSV101394218; called by muse, mutect2, varscan2
- PTPRN2 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101233426; called by muse, mutect2, varscan2
- PTPRT | c.2361G>C p.Q787H | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.707); catalogued as COSV100624308; called by muse, mutect2, varscan2
- RAB5C | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.155); catalogued as COSV100651366; called by muse, mutect2, varscan2
- RABGGTB | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99590332; called by muse, mutect2, varscan2
- RADIL | c.483G>C p.K161N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs1229944698, COSV68200270; called by muse, mutect2, varscan2
- RALBP1 | c.1011G>C p.M337I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99191863; called by muse, mutect2, varscan2
- RANBP6 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs759758598, COSV52389018; called by muse, mutect2
- RASGEF1C | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV100745416; called by muse, mutect2
- RELN | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100631940; called by muse, mutect2, varscan2
- RFPL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs1256420207, COSV100585575; called by muse, mutect2, varscan2
- RFX7 | c.2326G>T p.E776* (on ENST00000559447 / NM_001368074.1; = p.E873* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100428046, COSV57970033; called by muse, mutect2, varscan2
- RGS12 | c.3323G>C p.R1108T | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as COSV100122443; called by muse, mutect2, varscan2
- RHOA | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.498); catalogued as COSV101346261; called by muse, mutect2, varscan2
- RICTOR | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV57127865; called by muse, mutect2, varscan2
- RNF39 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.048); catalogued as COSV99748032; called by muse, mutect2, varscan2
- RNLS | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV100076106, COSV59292083; called by muse, mutect2, varscan2
- ROCK2 | c.1546C>G p.Q516E | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99836879; called by muse, mutect2, varscan2
- RP1 | c.4171C>G p.Q1391E | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99605805; called by muse, mutect2, varscan2
- RPN2 | c.963G>C p.Q321H | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV99411304; called by muse, mutect2, varscan2
- RPRD1A | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100441758, COSV61361245; called by muse, mutect2, varscan2
- RPS6KC1 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100873732; called by muse, mutect2, varscan2
- RSPO4 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV99448689; called by muse, mutect2, varscan2
- S1PR4 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99858848; called by muse, mutect2, varscan2
- SART3 | c.1876A>C p.K626Q (on ENST00000228284; = p.K608Q on NM_014706.4) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs751489897, COSV99933776; called by muse, mutect2, varscan2
- SCAMP3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs751039504, COSV56944296; called by muse, varscan2
- SCO1 | c.692G>C p.R231T | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99703471; called by muse, mutect2, varscan2
- SCUBE1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757682499, COSV62615632; called by mutect2, varscan2
- SEMA3A | c.548-1G>C p.X183_splice | Splice Site (SNP) | VAF 36/162 reads (22%) | catalogued as COSV99544667; called by muse, mutect2, varscan2
- SEMA4D | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372587621; called by mutect2, varscan2
- SENP3 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99548635, COSV99549285; called by muse, mutect2, varscan2
- SEPTIN11 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs759170909, COSV99345948; called by muse, varscan2
- SESN1 | c.917G>C p.R306T (on ENST00000356644 / NM_001199933.1; = p.R365T on NM_014454.3) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100122649, COSV104402203; called by muse, mutect2, varscan2
- SESN1 | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100425657; called by muse, mutect2, varscan2
- SF3A3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV100885575; called by muse, mutect2, varscan2
- SFMBT2 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100738253; called by muse, mutect2, varscan2
- SFRP4 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.592); catalogued as COSV99554156; called by muse, mutect2, varscan2
- SGCE | c.1082C>T p.S361L (on ENST00000647096; = p.S325L on NM_003919.3) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs559353446, CD032135, COSV56017126, COSV56018835, COSV99722218; called by muse, mutect2, varscan2
- SH3BP4 | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100748956; called by muse, mutect2, varscan2
- SH3TC1 | c.2201C>G p.S734* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99794255; called by muse, mutect2, varscan2
- SH3TC2 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100100967; called by muse, mutect2, varscan2
- SHF | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV99334145; called by muse, mutect2, varscan2
- SHH | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.822); catalogued as COSV99793211; called by muse, mutect2, varscan2
- SHROOM4 | c.1915C>G p.L639V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV99172945; called by muse, mutect2, varscan2
- SLC10A2 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99807484; called by muse, mutect2, varscan2
- SLC16A12 | c.669G>C p.L223F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57949299; called by muse, mutect2, varscan2
- SLC23A3 | c.766C>G p.H256D (on ENST00000409878 / NM_001144889.2; = p.L245= on NM_144712.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV99840776; called by muse, varscan2
- SLC25A16 | c.438C>G p.I146M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as COSV99769966; called by muse, varscan2
- SLC39A6 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs199955982, COSV99309265; called by muse, mutect2
- SLC4A10 | c.1243T>G p.S415A (on ENST00000446997 / NM_001354461.2; = p.S385A on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99761863; called by muse, mutect2
- SLC4A5 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100697320; called by muse, mutect2, varscan2
- SLC5A2 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57890801; called by muse, varscan2
- SLC9A5 | c.1441C>G p.L481V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100236960, COSV55360075; called by muse, varscan2
- SLCO4A1 | c.377C>G p.T126R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99414377; called by muse, mutect2, varscan2
- SLCO4A1 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 37/138 reads (27%) | catalogued as rs960796255, COSV99414379; called by muse, mutect2, varscan2
- SLIT2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.196); catalogued as COSV99879859; called by muse, mutect2, varscan2
- SLX4 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV99567474; called by muse, mutect2, varscan2
- SMARCA4 | c.3900G>C p.E1300D | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV100758003; called by muse, varscan2
- SMARCA5 | c.1421C>T p.T474I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV99303330; called by muse, mutect2, varscan2
- SNAP91 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV99534011; called by muse, mutect2, varscan2
- SNAPC4 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs746705123, COSV100046668; called by muse, mutect2, varscan2
- SNX33 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as COSV57913862; called by muse, mutect2, varscan2
- SNX5 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.417); catalogued as COSV100898952; called by muse, mutect2, varscan2
- SP2 | c.1205C>G p.S402* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100947082; called by muse, mutect2, varscan2
- SPATA20 | c.1047C>G p.F349L (on ENST00000356488 / NM_001258372.1; = p.F365L on NM_022827.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV50067185, COSV99135442; called by muse, mutect2, varscan2
- SPEN | c.6554C>A p.S2185Y | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV101004941, COSV65360462; called by muse, mutect2, varscan2
- SPEN | c.7506C>G p.I2502M | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.948); catalogued as COSV101004944; called by muse, varscan2
- SPHKAP | c.354G>C p.M118I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV100763564; called by muse, mutect2, varscan2
- SPTAN1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.322); catalogued as COSV100823150, COSV63987094; called by muse, mutect2, varscan2
- SRCAP | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1040520252, COSV99348932; called by muse, mutect2, varscan2
- STAT4 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as rs144091208, COSV61833074; called by muse, mutect2, varscan2
- STX1A | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV99767287; called by muse, mutect2, varscan2
- SULF1 | c.2542C>T p.L848F | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.361); catalogued as COSV52680050, COSV99481742; called by muse, mutect2, varscan2
- SULF2 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100736914; called by muse, mutect2, varscan2
- SULT1C4 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99731418; called by muse, mutect2, varscan2
- SURF6 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs1202970291, COSV64395540; called by muse, mutect2, varscan2
- SUV39H2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100542938; called by muse, mutect2, varscan2
- SVIL | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.058); catalogued as rs142485178; called by muse, mutect2, varscan2
- SYT1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV99693144; called by muse, mutect2, varscan2
- TARBP1 | c.3670C>G p.Q1224E | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1289168256, COSV99240947; called by muse, mutect2, varscan2
- TAS2R10 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as COSV53701953; called by muse, varscan2
- TASP1 | c.1171-1G>A p.X391_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100534298; called by muse, mutect2
- TBCK | c.2164G>C p.D722H (on ENST00000273980 / NM_001163436.4; = p.D659H on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99911906; called by muse, mutect2, varscan2
- TBX10 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100105412; called by muse, varscan2
- TBX10 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs781185047, COSV100105416; called by muse, varscan2
- TCEAL6 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV65654311; called by muse, mutect2, varscan2
- TCERG1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.885); catalogued as COSV99694281; called by muse, mutect2, varscan2
- TENT5C | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV101032686; called by muse, mutect2, varscan2
- TESK2 | c.348C>A p.F116L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV100516939, COSV59149399; called by muse, mutect2, varscan2
- TFB2M | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63621002; called by muse, mutect2, varscan2
- TG | c.8024C>T p.S2675L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99598442; called by muse, mutect2, varscan2
- THEMIS | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100965202; called by muse, mutect2, varscan2
- TLR1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100458266; called by muse, mutect2, varscan2
- TLR4 | c.935C>T p.S312L (on ENST00000355622 / NM_138554.5; = p.S272L on NM_003266.4) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV62924203; called by muse, mutect2, varscan2
- TMC7 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV100432198, COSV58586995; called by muse, varscan2
- TMCC1 | c.1670C>T p.T557M (on ENST00000393238 / NM_001349268.2; = p.T233M on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100260671; called by muse, mutect2, varscan2
- TMCO5A | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.851); catalogued as rs756502146, COSV60464403; called by muse, mutect2, varscan2
- TMEM252 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as rs1028117078, COSV101051069, COSV66065519; called by muse, mutect2, varscan2
- TNS4 | c.1721C>A p.S574Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99563479; called by muse, mutect2, varscan2
- TOM1 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV65898312; called by muse, mutect2, varscan2
- TPRX1 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100445444; called by muse, mutect2, varscan2
- TRAIP | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV100512945; called by muse, mutect2, varscan2
- TRERF1 | c.2670G>C p.W890C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100549718; called by muse, mutect2
- TRHDE | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV53843951; called by muse, mutect2, varscan2
- TRIO | c.890C>G p.S297* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100709604; called by muse, mutect2, varscan2
- TRMT10A | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 31/153 reads (20%) | catalogued as COSV99910785; called by muse, mutect2, varscan2
- TRPC1 | c.926G>A p.R309H (on ENST00000476941 / NM_001251845.2; = p.R275H on NM_003304.4) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748271979, COSV56426460; called by muse, mutect2, varscan2
- TRPV6 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100844051; called by muse, mutect2, varscan2
- TSC1 | c.3313G>A p.D1105N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100050883; called by muse, mutect2, varscan2
- TTN | c.75964G>A p.E25322K (on ENST00000591111; = p.E17898K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | PolyPhen benign (0.347); catalogued as COSV100589421; called by muse, mutect2, varscan2
- TTN | c.4720G>A p.E1574K (on ENST00000591111; = p.E1528K on NM_003319.4) | Missense Mutation (SNP) | VAF 31/145 reads (21%) | PolyPhen benign (0.011); catalogued as COSV100589422; called by muse, varscan2
- UBE3A | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.345); catalogued as COSV99216594; called by muse, mutect2, varscan2
- UBE4A | c.1687C>T p.R563* (on ENST00000252108 / NM_001204077.2; = p.R570* on NM_004788.4) | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as rs1555125936, COSV99347759; called by muse, mutect2, varscan2
- UBXN8 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV99667851; called by muse, mutect2, varscan2
- UNC79 | c.6954G>A p.M2318I (on ENST00000393151 / NM_001346218.2; = p.M2141I on NM_020818.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV99825235; called by muse, mutect2, varscan2
- UPF2 | c.2162A>T p.H721L | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100706832; called by muse, mutect2, varscan2
- USP16 | c.1031-1G>C p.X344_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100537753; called by muse, mutect2
- USP40 | c.2648G>A p.G883E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52481012, COSV99295602; called by muse, mutect2
- VPS13D | c.7655C>T p.S2552L | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99165319; called by muse, mutect2, varscan2
- VWCE | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100075469; called by muse, mutect2, varscan2
- VWF | c.5176C>T p.R1726C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs751816462, COSV54613781, COSV54621124; called by muse, mutect2, varscan2
- WDR70 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1474602507, COSV99457054; called by muse, mutect2, varscan2
- XPNPEP2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100941124; called by muse, mutect2, varscan2
- YEATS2 | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 53/278 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV100527351; called by muse, mutect2, varscan2
- ZBBX | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 84/250 reads (34%) | catalogued as COSV56791760, COSV56801465; called by muse, mutect2, varscan2
- ZBED4 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs757638894, COSV99350657; called by muse, mutect2, varscan2
- ZBTB22 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56472331, COSV99801267; called by muse, mutect2, varscan2
- ZC2HC1A | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753236294, COSV99803662; called by muse, mutect2, varscan2
- ZC2HC1C | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99472775; called by muse, mutect2, varscan2
- ZC3H18 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs1409200391, COSV99963742; called by muse, mutect2, varscan2
- ZCCHC4 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as rs1320315640, COSV100254925, COSV57182522; called by muse, mutect2, varscan2
- ZEB1 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.212); catalogued as COSV58054909; called by muse, mutect2, varscan2
- ZFHX4 | c.1311G>C p.E437D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99254510; called by muse, mutect2, varscan2
- ZFP91 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100284272; called by muse, mutect2, varscan2
- ZHX2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as COSV100072426; called by muse, mutect2, varscan2
- ZMPSTE24 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs373684692, COSV65639406, COSV65640266; called by muse, mutect2, varscan2
- ZMYND12 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.122); catalogued as COSV100999738; called by muse, mutect2, varscan2
- ZNF135 | c.598G>C p.D200H (on ENST00000313434 / NM_001289401.2; = p.D212H on NM_003436.4) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as COSV57885359; called by muse, mutect2, varscan2
- ZNF202 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs756925638, COSV60247219; called by muse, mutect2, varscan2
- ZNF217 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV100184098; called by muse, mutect2, varscan2
- ZNF382 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs772538250, COSV53086703, COSV99497265; called by muse, mutect2, varscan2
- ZNF396 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV100108406; called by muse, mutect2, varscan2
- ZNF43 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV61683645; called by muse, mutect2, varscan2
- ZNF569 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100386219, COSV100386587; called by muse, mutect2, varscan2
- ZNF585B | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100459244; called by muse, mutect2, varscan2
- ZNF709 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as COSV101172055; called by muse, varscan2
- ZNF750 | c.84C>G p.F28L | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99489468; called by muse, mutect2, varscan2
- ZNF750 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567855121, COSV99489471; called by muse, mutect2, varscan2
- DUSP14 | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GIT2 | c.1240_1242del p.K414del (on ENST00000355312 / NM_057169.5; = p.K416del on NM_014776.5) | In Frame Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- MAGEC3 | c.1265del p.P422Lfs*62 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel
- NBPF1 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 29/438 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NBPF11 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRAV39 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- AC005324.2 | c.69C>G p.L23= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV60887408; called by muse, mutect2, varscan2
- AC008397.2 | c.609G>A p.Q203= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99441016; called by muse, mutect2, varscan2
- ACVR1C | c.264C>T p.F88= | Silent (SNP) | VAF 45/246 reads (18%) | catalogued as COSV99694262; called by muse, mutect2, varscan2
- ADAMTS7 | c.735G>A p.E245= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs766259702, COSV101182991, COSV101183019; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1746C>G p.V582= | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as COSV99646528; called by muse, mutect2, varscan2
- ADORA2A | c.1002C>T p.V334= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100417772; called by muse, mutect2
- AHNAK | c.14427C>T p.I4809= | Silent (SNP) | VAF 125/423 reads (30%) | catalogued as rs199992585, COSV99945167; called by muse, mutect2, varscan2
- ALDOA | c.1041G>A p.L347= (on ENST00000642816 / NM_001243177.4; = p.L293= on NM_184041.5) | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs756568844, COSV100581857; called by muse, mutect2, varscan2
- ALG14 | c.132G>C p.G44= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV100930810; called by muse, mutect2, varscan2
- ANO9 | c.1308C>T p.L436= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100240707; called by muse, mutect2, varscan2
- AOPEP | c.2143C>T p.L715= (on ENST00000375315 / NM_001193329.1; = p.L616= on NM_032823.5) | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs1307029241, COSV99948398; called by muse, mutect2, varscan2
- APOBEC3A | c.599G>A p.*200= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as rs1426866198, COSV99970271; called by muse, mutect2, varscan2
- ATP1A3 | c.930C>T p.F310= (on ENST00000545399 / NM_001256214.2; = p.F297= on NM_152296.5) | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs921400561, COSV100131798; ClinVar: likely benign; called by muse, mutect2, varscan2
- BATF2 | c.633G>A p.L211= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100101657; called by muse, mutect2, varscan2
- BCL7C | c.621C>G p.L207= | Silent (SNP) | VAF 64/228 reads (28%) | catalogued as COSV99288448; called by muse, mutect2, varscan2
- BMPR1B | c.576C>G p.L192= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV52781758, COSV99215229; called by muse, mutect2, varscan2
- BRINP2 | c.1527G>A p.L509= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100837786, COSV64176344; called by muse, mutect2, varscan2
- BTBD2 | c.957C>T p.F319= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV99724449; called by muse, mutect2
- BTBD3 | c.342C>T p.F114= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99655562; called by muse, mutect2, varscan2
- C12orf60 | c.444C>T p.I148= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV57451291; called by muse, mutect2, varscan2
- CAMTA1 | c.3252C>T p.L1084= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100345295; called by muse, mutect2, varscan2
- CAPRIN2 | c.1830G>A p.P610= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs776463295, COSV51833769; called by muse, mutect2, varscan2
- CBLB | c.156C>G p.L52= | Silent (SNP) | VAF 36/212 reads (17%) | catalogued as COSV99912441; called by muse, mutect2, varscan2
- CCDC191 | c.1389G>A p.V463= | Silent (SNP) | VAF 37/214 reads (17%) | catalogued as COSV99877824; called by muse, mutect2, varscan2
- CCDC8 | c.1416G>A p.R472= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100281813; called by muse, mutect2, varscan2
- CELSR2 | c.7077C>T p.F2359= | Silent (SNP) | VAF 59/247 reads (24%) | catalogued as rs1189095778, COSV54766617; called by muse, mutect2, varscan2
- CEP192 | c.4866C>T p.I1622= | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as rs527904087, COSV58060069; called by muse, mutect2, varscan2
- CFAP65 | c.3735G>C p.G1245= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100444420; called by muse, mutect2, varscan2
- CKMT2 | c.1008C>A p.L336= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99562218; called by muse, mutect2
- CLPTM1 | c.1107C>G p.V369= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100493536; called by muse, mutect2, varscan2
- CPSF3 | c.888G>A p.Q296= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV99432350; called by muse, mutect2, varscan2
- CYGB | c.276C>T p.V92= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs148657053; called by muse, varscan2
- CYP4A22 | c.1527C>G p.L509= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99594524; called by muse, mutect2, varscan2
- DDX39A | c.585C>T p.D195= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs769807109, COSV99660072; called by muse, mutect2
- DENND5A | c.879C>T p.L293= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs772057315, COSV100063820; called by muse, mutect2, varscan2
- DNAH3 | c.3480G>A p.L1160= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV54540180; called by muse, mutect2, varscan2
- DNAH3 | c.627C>T p.L209= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs201448297, COSV54521646, COSV54546148; called by muse, mutect2, varscan2
- DNPEP | c.921C>G p.L307= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs1466393728, COSV99815006; called by muse, mutect2, varscan2
- DSG2 | c.1599C>G p.V533= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99852598; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.543G>A p.L181= | Silent (SNP) | VAF 42/188 reads (22%) | catalogued as rs764931462, COSV100766084; called by muse, mutect2, varscan2
- EHBP1L1 | c.2529G>A p.E843= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100499554; called by muse, mutect2, varscan2
- EHD2 | c.366C>T p.F122= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1220427390, COSV99621501; called by muse, mutect2, varscan2
- EIF4G2 | c.1378C>A p.R460= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as rs746458672, COSV60596336, COSV60598957; called by muse, mutect2, varscan2
- EMILIN1 | c.1971C>G p.L657= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99565649; called by muse, mutect2, varscan2
- ENTPD8 | c.1473C>T p.F491= (on ENST00000371506 / NM_001033113.2; = p.F454= on NM_198585.3) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100395411; called by muse, mutect2, varscan2
- EPB41L1 | c.2280C>T p.L760= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99148744; called by muse, mutect2
- FAM111A | c.180C>T p.F60= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as COSV100659306; called by muse, mutect2, varscan2
- FAM118A | c.270C>T p.V90= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs1056797046, COSV99343294; called by muse, mutect2, varscan2
- FBN3 | c.1137A>T p.R379= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99559354; called by muse, mutect2, varscan2
- FBXL20 | c.802C>T p.L268= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs1325271697, COSV99233611; called by muse, mutect2, varscan2
- FCRL4 | c.585G>A p.L195= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV99619121; called by muse, mutect2, varscan2
- FLT3 | c.2107C>T p.L703= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as COSV54045363; called by muse, mutect2, varscan2
- FOXB2 | c.174G>A p.Q58= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV65022801; called by muse, mutect2, varscan2
- FOXN2 | c.126G>A p.P42= | Silent (SNP) | VAF 26/133 reads (20%) | catalogued as rs755184660, COSV61319830; called by muse, mutect2, varscan2
- FRMD5 | c.312G>A p.L104= | Silent (SNP) | VAF 60/279 reads (22%) | catalogued as COSV101296225; called by muse, mutect2, varscan2
- FUT11 | c.1455C>T p.I485= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV100226444, COSV100226523; called by muse, mutect2, varscan2
- GAB4 | c.1311G>C p.L437= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV101271840; called by muse, mutect2, varscan2
- GAPDHS | c.1077C>G p.L359= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as COSV55881393; called by muse, mutect2, varscan2
- GDPGP1 | c.741C>T p.L247= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs1048672722, COSV100291974; called by muse, mutect2, varscan2
- GPR139 | c.606G>A p.L202= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100429555; called by muse, mutect2, varscan2
- GPR50 | c.540C>T p.F180= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as COSV99505504; called by muse, mutect2, varscan2
- GPRASP1 | c.627C>G p.V209= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as COSV100850885; called by muse, mutect2, varscan2
- GPSM3 | c.420G>A p.L140= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV100900265, COSV66681034; called by muse, mutect2, varscan2
- GRM8 | c.1086C>T p.F362= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- H2AC21 | c.324C>G p.V108= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1275013172, COSV58611702; called by muse, mutect2, varscan2
- HDLBP | c.3438C>T p.R1146= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs11555546, COSV60500692; called by muse, mutect2, varscan2
- HIF3A | c.396C>T p.F132= (on ENST00000377670 / NM_152795.4; = p.F63= on NM_022462.4) | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as COSV99355403; called by muse, mutect2, varscan2
- HMCN1 | c.12001C>T p.L4001= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV99622547; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1212C>T p.L404= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs1031057100, COSV100079292; called by muse, mutect2, varscan2
- HOXB7 | c.240C>G p.L80= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs777513955, COSV99493840; called by muse, varscan2
- HPS3 | c.483G>A p.L161= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as COSV99937069; called by muse, varscan2
- HTT | c.9129C>T p.F3043= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100750259; called by muse, mutect2
- IK | c.93C>T p.L31= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99347508; called by muse, mutect2
- INSR | c.270C>T p.L90= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs749842691, COSV100251110; called by muse, mutect2, varscan2
- INTS9 | c.984C>T p.F328= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs755466448, COSV101273770; called by muse, varscan2
- INTS9 | c.948C>T p.I316= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs746827957, COSV101273771; called by muse, varscan2
- ISG15 | c.174C>T p.V58= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV101046047; called by muse, mutect2, varscan2
- ITIH1 | c.2310G>A p.L770= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV99834833; called by muse, mutect2, varscan2
- KIAA0513 | c.885G>A p.L295= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99260313; called by muse, mutect2, varscan2
- KIF17 | c.288G>A p.G96= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99928299; called by muse, mutect2
- KMT2D | c.480G>A p.V160= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99976605; called by muse, mutect2
- KNL1 | c.3240G>A p.L1080= (on ENST00000346991 / NM_170589.5; = p.L1054= on NM_144508.5) | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs753821813, COSV100705756; called by muse, mutect2, varscan2
- KRT5 | c.633G>A p.V211= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV99357695; called by muse, mutect2, varscan2
- LMNB2 | c.528C>T p.D176= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs749717016, COSV100321863; called by muse, mutect2
- LMOD1 | c.1239G>A p.Q413= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100939063; called by muse, mutect2
- LONP2 | c.1578G>A p.L526= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV99588714; called by muse, mutect2, varscan2
- LRP1B | c.4077C>T p.I1359= | Silent (SNP) | VAF 39/175 reads (22%) | catalogued as rs377677860, COSV67233356; called by muse, mutect2, varscan2
- LRRC8C | c.484C>T p.L162= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV100967870; called by muse, mutect2, varscan2
- LRRC8C | c.744C>T p.F248= | Silent (SNP) | VAF 49/230 reads (21%) | catalogued as COSV100967873; called by muse, mutect2, varscan2
- LRRC8C | c.2329C>T p.L777= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV100967876; called by muse, mutect2, varscan2
- LRRIQ1 | c.567C>T p.L189= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as COSV101277686; called by muse, mutect2, varscan2
- MAGEB6B | c.51G>A p.E17= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV69689974; called by muse, mutect2, varscan2
- MAST1 | c.3843G>C p.A1281= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99262044, COSV99262364; called by muse, varscan2
- MBD3 | c.471G>A p.K157= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99336807; called by muse, mutect2
- MED17 | c.1035G>A p.L345= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV99315621; called by muse, mutect2, varscan2
- MED29 | c.6G>A p.L2= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99655536; called by muse, mutect2, varscan2
- METTL2A | c.975C>T p.F325= | Silent (SNP) | VAF 61/292 reads (21%) | catalogued as rs1195695129, COSV100274078, COSV61046092; called by muse, mutect2, varscan2
- MROH7 | c.1911C>G p.L637= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as COSV100272703; called by muse, mutect2, varscan2
- MRPS16 | c.249C>G p.L83= | Silent (SNP) | VAF 67/232 reads (29%) | catalogued as COSV100160034; called by muse, mutect2, varscan2
- MRPS7 | c.210G>A p.K70= | Silent (SNP) | VAF 57/246 reads (23%) | catalogued as COSV99821429; called by muse, mutect2, varscan2
- MYBPC1 | c.2814G>A p.V938= (on ENST00000550270 / NM_206820.2; = p.V945= on NM_002465.4) | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100637677; called by muse, mutect2, varscan2
- MYBPC2 | c.2736G>T p.L912= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV100731511; called by muse, mutect2, varscan2
- MYO1B | c.978C>T p.F326= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as rs532881047, COSV100268399; called by muse, mutect2, varscan2
- NAALADL2 | c.2199C>G p.L733= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV101495133; called by muse, mutect2
- NAGK | c.921G>A p.L307= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99730418; called by muse, mutect2, varscan2
- NETO1 | c.1341C>T p.L447= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV100198028; called by muse, mutect2, varscan2
- NIPBL | c.123C>G p.L41= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as COSV99238250; called by muse, mutect2, varscan2
- NOTCH2 | c.3465C>T p.S1155= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV99862350; called by muse, mutect2, varscan2
- NOTCH4 | c.5703G>C p.S1901= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs765352408, COSV100900267; called by muse, mutect2
- NOX5 | c.2193G>A p.K731= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV99533058; called by muse, mutect2, varscan2
- NR4A2 | c.1779G>A p.L593= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as rs141522485; called by muse, mutect2, varscan2
- NSUN6 | c.462T>A p.I154= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV101045256; called by muse, mutect2, varscan2
- OR4L1 | c.240G>A p.K80= | Silent (SNP) | VAF 98/195 reads (50%) | catalogued as COSV100235521; called by muse, mutect2, varscan2
- OR52K1 | c.282C>A p.I94= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs768344079, COSV56904478; called by muse, mutect2, varscan2
- OR5D18 | c.816C>T p.V272= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV100450427; called by muse, mutect2, varscan2
- OSBPL7 | c.2019C>T p.F673= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1010132842, COSV99136492; called by muse, mutect2, varscan2
- OSR1 | c.621C>T p.I207= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99693498; called by muse, mutect2, varscan2
- PDIA5 | c.621G>A p.G207= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1377479074, COSV100299065; called by muse, mutect2, varscan2
- PEBP1 | c.291C>A p.I97= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV99731781; called by muse, mutect2, varscan2
- PGBD4 | c.564C>G p.L188= | Silent (SNP) | VAF 58/224 reads (26%) | catalogued as COSV99854681; called by muse, mutect2, varscan2
- PLAA | c.2163G>C p.G721= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV68305386; called by muse, mutect2, varscan2
- PLXNA1 | c.4056G>A p.E1352= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99302074; called by muse, mutect2, varscan2
- PMPCB | c.63C>T p.F21= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99971042; called by muse, mutect2
- POR | c.252C>T p.I84= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs782768141, COSV101203458; called by muse, mutect2, varscan2
- PPP4R4 | c.660C>G p.L220= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100428159; called by muse, mutect2, varscan2
- PSIP1 | c.1320G>A p.L440= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as rs755366665, COSV101050866; called by muse, mutect2, varscan2
- PTPRG | c.525G>A p.Q175= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99872304; called by muse, mutect2, varscan2
- PTPRU | c.2952C>T p.I984= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs140673849; called by muse, mutect2, varscan2
- RANBP2 | c.8898G>A p.K2966= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV99311028; called by muse, mutect2, varscan2
- RBBP8 | c.2232C>T p.F744= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV100506966; called by muse, mutect2, varscan2
- RBM47 | c.984G>A p.Q328= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1428035462, COSV99919955; called by muse, mutect2, varscan2
- RFX7 | c.1818G>T p.G606= (on ENST00000559447 / NM_001368074.1; = p.G703= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs903253911, COSV100428052; called by muse, mutect2, varscan2
- RFX7 | c.1422G>A p.Q474= (on ENST00000559447 / NM_001368074.1; = p.Q571= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100428053; called by muse, varscan2
- RFX7 | c.1227G>A p.R409= (on ENST00000559447 / NM_001368074.1; = p.R506= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100428064; called by muse, mutect2, varscan2
- RPN2 | c.1353C>T p.A451= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs200454814, COSV99411307; called by muse, mutect2, varscan2
- SAP130 | c.1224T>C p.I408= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV99383978; called by muse, mutect2, varscan2
- SBDS | c.558G>A p.L186= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV99885804; called by muse, mutect2, varscan2
- SBF1 | c.1515C>T p.F505= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV62370397; called by muse, mutect2, varscan2
- SCRN1 | c.474G>C p.L158= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs778558042, COSV99620629; called by muse, mutect2, varscan2
- SFN | c.594C>T p.F198= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100212760; called by muse, mutect2, varscan2
- SFTPB | c.561G>A p.A187= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs543913426, COSV60892598; called by muse, mutect2, varscan2
- SGSM1 | c.2394G>C p.R798= (on ENST00000400359 / NM_001039948.4; = p.R737= on NM_133454.3) | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100771842, COSV63082648; called by muse, mutect2, varscan2
- SKIV2L | c.58C>A p.R20= | Silent (SNP) | VAF 97/422 reads (23%) | catalogued as COSV100952542, COSV64812555; called by muse, mutect2, varscan2
- SLC35D1 | c.685C>T p.L229= | Silent (SNP) | VAF 56/284 reads (20%) | catalogued as COSV99337899; called by muse, mutect2, varscan2
- SLC6A19 | c.1413C>T p.F471= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1205149103, COSV100443138; called by muse, mutect2, varscan2
- SMPD1 | c.375G>A p.L125= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100192220; called by muse, mutect2, varscan2
- SORCS1 | c.3312G>A p.L1104= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV53899440, COSV99542182; called by muse, mutect2, varscan2
- SORT1 | c.1512T>C p.D504= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99860393; called by muse, mutect2, varscan2
- SPAG16 | c.1674C>T p.I558= | Silent (SNP) | VAF 27/193 reads (14%) | catalogued as rs376387182; called by muse, mutect2, varscan2
- SPATA20 | c.1305C>G p.L435= (on ENST00000356488 / NM_001258372.1; = p.L451= on NM_022827.4) | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV99135445; called by muse, mutect2, varscan2
- SPEN | c.7401C>T p.I2467= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV101004942; called by muse, mutect2, varscan2
- SPHKAP | c.4932G>A p.K1644= (on ENST00000392056 / NM_001142644.2; = p.K1615= on NM_030623.3) | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100763563; called by muse, mutect2, varscan2
- SPNS1 | c.694C>T p.L232= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100208817; called by muse, mutect2, varscan2
- SPPL2B | c.906C>G p.L302= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV101194566; called by muse, mutect2, varscan2
- SRSF2 | c.399G>A p.R133= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100333370; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.147G>A p.E49= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV99336172; called by muse, mutect2, varscan2
- STAG1 | c.1926C>T p.I642= | Silent (SNP) | VAF 45/322 reads (14%) | catalogued as COSV99364067; called by muse, mutect2, varscan2
- SYTL1 | c.978G>A p.L326= (on ENST00000543823; = p.L314= on NM_032872.3) | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV100538994; called by muse, mutect2, varscan2
- TACC2 | c.4465C>T p.L1489= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs775971633, COSV100551263; called by muse, mutect2
- TAS2R10 | c.696C>T p.F232= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV99555385; called by muse, varscan2
- TBC1D1 | c.1755G>A p.S585= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs202224734, COSV54713755; called by muse, mutect2, varscan2
- TECPR2 | c.1962C>T p.L654= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100849770; called by muse, mutect2, varscan2
- THBS1 | c.36G>C p.L12= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99527428; called by muse, mutect2
- TMEM132D | c.3195C>T p.I1065= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as rs776600445, COSV67158685; called by muse, mutect2, varscan2
- TNFSF4 | c.510G>C p.L170= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV99919214; called by muse, mutect2, varscan2
- TNS4 | c.1611C>T p.F537= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs749374357, COSV99563482; called by muse, mutect2, varscan2
- TRANK1 | c.7167C>T p.F2389= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV57143897; called by muse, mutect2, varscan2
- TRIM58 | c.603G>A p.L201= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs773657378, COSV100824783; called by muse, mutect2, varscan2
- TRPC5 | c.2526C>G p.L842= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV99458981; called by muse, mutect2, varscan2
- TULP1 | c.1092G>A p.E364= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100003783; called by muse, mutect2, varscan2
- UGT1A5 | c.225C>T p.F75= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV59399916; called by muse, mutect2, varscan2
- USP29 | c.1533G>A p.L511= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV54143028; called by muse, mutect2, varscan2
- VN1R1 | c.240G>A p.L80= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100320559; called by muse, mutect2, varscan2
- WIPI1 | c.705C>T p.I235= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100048144; called by muse, mutect2, varscan2
- XKR4 | c.513C>T p.F171= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100530274; called by muse, mutect2, varscan2
- XPOT | c.552G>A p.V184= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV100225277; called by muse, mutect2, varscan2
- ZNF20 | c.633C>G p.L211= | Silent (SNP) | VAF 61/334 reads (18%) | catalogued as COSV100502787; called by muse, mutect2, varscan2
- ZNF445 | c.1734C>T p.L578= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs771256016, COSV101253646; called by muse, mutect2, varscan2
- ZNF551 | c.1359G>A p.G453= | Silent (SNP) | VAF 40/136 reads (29%) | catalogued as rs1427489189, COSV99989656; called by muse, mutect2, varscan2
- ZNF626 | c.846G>A p.K282= | Silent (SNP) | VAF 80/230 reads (35%) | catalogued as COSV101656926, COSV101656999; called by muse, mutect2, varscan2
- ZNF630 | c.138C>T p.S46= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs781822284, COSV52097908; called by muse, mutect2, varscan2
- ZNF709 | c.1587G>A p.E529= | Silent (SNP) | VAF 57/326 reads (17%) | catalogued as COSV101172056; called by muse, varscan2
- ZNF831 | c.3234C>T p.L1078= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100925707; called by muse, mutect2, varscan2
- CREM | c.698-5381G>C | Intron (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100414907, COSV59766353; called by muse, mutect2, varscan2
- HMGA2 | c.250-36295G>T | Intron (SNP) | VAF 37/194 reads (19%) | catalogued as COSV63591321; called by muse, mutect2, varscan2
- OPN4 | c.291-810G>A | Intron (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99617896; called by muse, mutect2, varscan2
- OR2U1P | n.744C>T | RNA (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- PREX2 | c.2716-2855C>G | Intron (SNP) | VAF 27/149 reads (18%) | catalogued as COSV99904291; called by muse, mutect2, varscan2
- SNORD115-42 | n.36G>C | RNA (SNP) | VAF 76/472 reads (16%) | called by muse, mutect2, varscan2
- SNX18 | chr5:54543378 C>A | 3'Flank (SNP) | VAF 23/109 reads (21%) | catalogued as COSV100543172; called by muse, mutect2, varscan2
